Somatic mutation profile of tumor specimen MMRF_2583_1_BM_CD138pos (aliquot MMRF_2583_1_BM_CD138pos_T1_KHS5U_L13288) from MMRF case MMRF_2583, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,939 days).
Specimen MMRF_2583_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42a810fc-3d46-4bda-b5b2-5c9a445af915.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2583_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2583_1_PB_WBC_C3_KHS5U_L13289; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14aaa747-3384-4fb3-b56c-9529c89e7587

The open-access MAF lists 82 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 17, Silent 13, Intron 12, 5'UTR 3, 5'Flank 3, In Frame Del 2, Splice Region 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPG | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs543090174, COSV71934154; called by muse, mutect2, varscan2
- ATP1A2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs748654627, COSV63403701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRDT | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142308966, COSV62863712; called by muse, mutect2, varscan2
- CACNA1H | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs375021293; called by muse, mutect2, varscan2
- DNAH5 | c.11528C>T p.S3843L | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs78346432, CM065132, COSV54202507; called by muse, mutect2, varscan2
- DPYSL4 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs770111367; called by muse, mutect2, varscan2
- GP2 | c.1325G>A p.R442Q (on ENST00000381362 / NM_001007240.3; = p.R439Q on NM_001502.4) | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as rs754880634; called by muse, mutect2, varscan2
- IGHV1-69 | c.6C>G p.D2E | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.976); catalogued as rs1555594434; called by muse, varscan2
- IGHV2-70 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs373471089; called by muse, varscan2
- IGLV3-1 | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as rs559078152; called by muse, mutect2, varscan2
- IGLV3-25 | c.137T>A p.L46* | Nonsense Mutation (SNP) | VAF 62/132 reads (47%) | catalogued as rs775320247; called by muse, mutect2, varscan2
- OR11H6 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1392787920, COSV59644603; called by muse, mutect2, varscan2
- PCNT | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1291503523, COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PLEKHG4B | c.3156G>A p.T1052= (on ENST00000283426; = p.T1408= on NM_052909.5) | Splice Region (SNP) | VAF 99/218 reads (45%) | catalogued as rs752524145; called by muse, mutect2, varscan2
- RECK | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750000887, COSV65035715; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54442003; called by muse, mutect2, varscan2
- AMBRA1 | c.1399A>G p.T467A (on ENST00000458649 / NM_001367468.1; = p.T377A on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CMYA5 | c.5101T>C p.S1701P | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.7163C>T p.A2388V | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DNMBP | c.1908_1931del p.L637_P644del | In Frame Del (DEL) | VAF 43/126 reads (34%) | called by mutect2, pindel, varscan2
- ECE1 | c.1424T>G p.F475C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENDOD1 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ICE2 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- IGHD2-8 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 32/32 reads (100%) | called by mutect2, varscan2
- IGLC2 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); called by mutect2, varscan2
- IGLV3-16 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- IGLV3-25 | c.253T>C p.S85P | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, varscan2
- KDM3B | c.2330T>A p.L777Q | Missense Mutation (SNP) | VAF 151/289 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KRT34 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- MYH1 | c.1073C>A p.A358D | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PARP2 | c.1742A>G p.Q581R | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- SALL3 | c.2623_2637del p.L875_S879del | In Frame Del (DEL) | VAF 56/145 reads (39%) | called by mutect2, pindel, varscan2
- SPAG16 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCA4 | c.849A>G p.R283= | Silent (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- CASP3 | c.684C>T p.D228= | Silent (SNP) | VAF 173/391 reads (44%) | called by muse, mutect2, varscan2
- CHAT | c.1173C>T p.D391= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as rs141690626; called by muse, mutect2, varscan2
- DNHD1 | c.7125C>T p.D2375= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- EIF5B | c.714C>T p.R238= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs750268998; called by muse, mutect2, varscan2
- IGLV3-25 | c.228C>T p.I76= | Silent (SNP) | VAF 67/148 reads (45%) | catalogued as rs573136412; called by muse, varscan2
- KRTAP4-7 | c.39G>A p.Q13= | Silent (SNP) | VAF 87/509 reads (17%) | called by muse, mutect2
- KRTAP4-9 | c.39G>A p.Q13= | Silent (SNP) | VAF 32/464 reads (7%) | catalogued as rs1324317430; called by muse, mutect2
- LRIG3 | c.1287A>G p.A429= | Silent (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- SYNPO | c.114G>A p.E38= | Silent (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- UBE2E3 | c.51T>C p.S17= | Silent (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- USP43 | c.1254C>T p.P418= | Silent (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- VCAN | c.6324A>G p.Q2108= | Silent (SNP) | VAF 112/238 reads (47%) | called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1247T>C | Intron (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- ADM | c.*671del | 3'UTR (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- AP000769.3 | chr11:65504894 T>C | 5'Flank (SNP) | VAF 81/215 reads (38%) | called by muse, mutect2, varscan2
- AP3D1 | c.2800-28C>T | Intron (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- BARD1 | c.1904-560A>T | Intron (SNP) | VAF 143/332 reads (43%) | catalogued as rs559735366; called by muse, varscan2
- BARD1 | c.1904-561T>C | Intron (SNP) | VAF 142/331 reads (43%) | called by muse, varscan2
- BARD1 | c.1904-634_1904-633insG | Intron (INS) | VAF 62/179 reads (35%) | called by pindel, varscan2
- C11orf87 | c.*1749C>T | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- CHMP6 | chr17:81004771 G>A | 3'Flank (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- CLCF1 | c.*791C>T | 3'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- COL1A1 | c.472-159G>C | Intron (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- EWSR1 | c.1165-74T>C | Intron (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- FCER2 | c.316+79G>A | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- GAREM2 | c.254-486A>T | Intron (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- IZUMO4 | c.298+36C>T | Intron (SNP) | VAF 174/247 reads (70%) | called by muse, mutect2, varscan2
- KCTD15 | c.*271C>T | 3'UTR (SNP) | VAF 37/112 reads (33%) | catalogued as rs1555731443; called by muse, mutect2, varscan2
- KIF6 | c.*556A>G | 3'UTR (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- MFSD11 | chr17:76737298 G>T | 5'Flank (SNP) | VAF 11/17 reads (65%) | catalogued as rs535772387; called by muse, mutect2, varscan2
- MYO1E | c.-55C>T | 5'UTR (SNP) | VAF 64/133 reads (48%) | catalogued as COSV99893901; called by muse, mutect2, varscan2
- NAPEPLD | c.*1999G>A | 3'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- NR5A1 | c.*1375C>T | 3'UTR (SNP) | VAF 37/102 reads (36%) | catalogued as rs1422800207; called by muse, mutect2, varscan2
- PARVA | c.*1633T>G | 3'UTR (SNP) | VAF 55/91 reads (60%) | called by muse, mutect2, varscan2
- PLA2G2C | c.*356C>T | 3'UTR (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- PRRC2B | c.*2872T>A | 3'UTR (SNP) | VAF 58/176 reads (33%) | called by muse, mutect2, varscan2
- RALYL | c.257-68578T>C | Intron (SNP) | VAF 207/268 reads (77%) | called by muse, mutect2, varscan2
- RNU6-354P | chr15:43736870 G>A | 5'Flank (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- SCN3B | c.*1719C>A | 3'UTR (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- SEMA3E | c.-345T>A | 5'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*1927C>T | 3'UTR (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- SLC25A31 | c.-124G>C | 5'UTR (SNP) | VAF 97/242 reads (40%) | catalogued as COSV55418622; called by muse, mutect2, varscan2
- TFAP2A | c.889+149G>A | Intron (SNP) | VAF 61/142 reads (43%) | catalogued as rs765317217; called by muse, mutect2, varscan2
- TMEM30A | c.*1807C>G | 3'UTR (SNP) | VAF 33/36 reads (92%) | catalogued as rs775023238; called by muse, mutect2, varscan2
- TNFRSF10D | c.*602G>A | 3'UTR (SNP) | VAF 18/21 reads (86%) | catalogued as rs541422201; called by muse, mutect2, varscan2
- TSPEAR | c.*1711T>G | 3'UTR (SNP) | VAF 52/161 reads (32%) | called by muse, mutect2, varscan2
- WDR64 | c.*489G>T | 3'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ZMAT3 | c.*6161G>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
